Somatic mutation profile of tumor specimen ALCH-AEOY-TTP1-A (aliquot ALCH-AEOY-TTP1-A-1-0-D-A636-36) from ALCHEMIST case ALCH-AEOY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 85.4 years (31,184 days).
Specimen ALCH-AEOY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb5dfd51-e47e-4219-891e-358b60c3f1c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEOY-NB1-A (Blood Derived Normal), aliquot ALCH-AEOY-NB1-A-1-0-D-A635-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77dc8e0c-f211-47b1-a4b8-7df4afbe0dcd

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 42/440 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSF2RA | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 18/499 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as rs767644484, COSV62624191; called by muse, mutect2
- CYTH1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV63120023; called by muse, mutect2
- KRT13 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs947507116; called by muse, mutect2
- NANOGNB | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.074); catalogued as rs1363620658, COSV66125185; called by muse, mutect2
- RASGRF1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 31/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69177935; called by muse, mutect2
- ANKRD13B | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- GAST | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 17/334 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.059); called by muse, mutect2
- MTMR4 | c.1565A>G p.N522S | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.082); called by muse, mutect2
- BCO1 | c.1491T>C p.F497= | Silent (SNP) | VAF 22/698 reads (3%) | catalogued as rs1400269947; called by muse, mutect2
- PHLDB1 | c.228G>A p.Q76= | Silent (SNP) | VAF 12/195 reads (6%) | called by muse, mutect2
- ZDHHC11 | c.552G>A p.L184= | Silent (SNP) | VAF 26/915 reads (3%) | catalogued as COSV52074692; called by muse, mutect2
- KIF21A | c.3671+11C>T | Intron (SNP) | VAF 45/430 reads (10%) | called by muse, mutect2, varscan2
- OPRM1 | c.-259C>A | 5'UTR (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
